CCDI case PBCEFF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ca88c7c6-cad3-4791-802c-62e71e750f30

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.8 years (6,151 days).

Biospecimens (3 samples)
- Sample 0DQ7W7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQ7WL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ80P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
